Somatic mutation profile of tumor specimen f4bccfe4-98d0-466b-a6d7-44341b (aliquot f4bccfe4-98d0-466b-a6d7-44341b_D6_1) from CPTAC case 11CO045, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen f4bccfe4-98d0-466b-a6d7-44341b: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b354033-d3f8-415c-b5b1-08b7cb363da3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 6e84e841-28fb-4443-8876-23c6bf (Blood Derived Normal), aliquot 6e84e841-28fb-4443-8876-23c6bf_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/643fc834-fa2a-437a-b0dc-8fb83a646ca6

The open-access MAF lists 260 somatic variants for this specimen: 173 protein-altering or splice-affecting, 56 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 145, Silent 56, Nonsense Mutation 13, Intron 12, 3'UTR 7, RNA 6, 5'UTR 4, Frame Shift Del 4, Splice Site 3, Splice Region 3, In Frame Del 2, Nonstop Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4285C>T p.Q1429* | Nonsense Mutation (SNP) | VAF 50/152 reads (33%) | hotspot (GDC flag); catalogued as rs74535574, HM050024, COSV57322632, COSV57333893; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 75/300 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.902del p.P301Qfs*44 | Frame Shift Del (DEL) | VAF 104/358 reads (29%) | catalogued as rs876660726, COSV53267099, COSV53486315; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABHD11 | c.609T>A p.D203E | Missense Mutation (SNP) | VAF 22/780 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.088); catalogued as COSV56105446; called by muse, mutect2
- ACAN | c.1004C>T p.T335M | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs370865297; called by muse, mutect2, varscan2
- ADGRG4 | c.5423C>A p.T1808K | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV54952238; called by muse, mutect2
- ARHGAP23 | c.3031C>T p.R1011W | Missense Mutation (SNP) | VAF 44/271 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as rs761771854; called by muse, mutect2, varscan2
- BPNT1 | c.172A>C p.I58L | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs773245779; called by muse, mutect2, varscan2
- CCM2L | c.137C>A p.P46H | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs149172226, COSV52950193; called by muse, mutect2, varscan2
- CD93 | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 66/176 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs140540216, COSV55664977; called by muse, mutect2, varscan2
- CHD8 | c.7199C>T p.T2400M (on ENST00000646647 / NM_001170629.2; = p.T2121M on NM_020920.4) | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as rs753527616; called by muse, mutect2, varscan2
- CHRNA4 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 160/455 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.54); catalogued as rs754312855; called by muse, mutect2, varscan2
- CHRNB2 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 12/328 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs1448877456; called by muse, mutect2
- CLCN7 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 72/473 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.381); catalogued as rs760871410; called by muse, mutect2, varscan2
- CNR1 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 85/300 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.954); catalogued as rs771165694; called by muse, mutect2, varscan2
- CPNE5 | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 53/186 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs369823408; called by muse, mutect2, varscan2
- CRKL | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 41/257 reads (16%) | catalogued as COSV62884159; called by muse, mutect2, varscan2
- CSF3R | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759364352; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSMD3 | c.8281G>A p.E2761K (on ENST00000297405 / NM_001363185.1; = p.E2592K on NM_052900.3) | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.779); catalogued as COSV52327398; called by muse, mutect2, varscan2
- DDX60 | c.4700G>A p.C1567Y | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs777203434; called by muse, mutect2, varscan2
- DIPK2B | c.858C>A p.F286L | Missense Mutation (SNP) | VAF 61/314 reads (19%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.954); catalogued as rs1325624372; called by muse, mutect2, varscan2
- EGFL6 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs751522241; called by muse, mutect2, varscan2
- EIF2AK4 | c.2039G>A p.R680Q | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs769775788; called by muse, mutect2, varscan2
- ELFN1 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 89/452 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.774); catalogued as rs556140343, COSV70035520; called by muse, varscan2
- EML6 | c.931C>T p.R311* | Nonsense Mutation (SNP) | VAF 106/412 reads (26%) | catalogued as rs925199993, COSV62864833; called by muse, mutect2, varscan2
- EP300 | c.4307G>T p.W1436L | Missense Mutation (SNP) | VAF 76/239 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54330637, COSV54343729; called by muse, mutect2, varscan2
- EXO1 | c.327G>C p.E109D | Missense Mutation (SNP) | VAF 62/224 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as rs141567727, COSV62220602; called by muse, mutect2, varscan2
- EXOC7 | c.200C>T p.T67M | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as rs144068878; called by muse, mutect2, varscan2
- FAM110B | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 44/244 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64063316; called by muse, mutect2, varscan2
- FAM135B | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 12/318 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.216); catalogued as COSV99417167, COSV99425393; called by muse, mutect2
- FICD | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 49/279 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as rs777654791, COSV57209190; called by muse, mutect2, varscan2
- GNAZ | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 11/313 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99320364; called by muse, mutect2
- GPATCH1 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99403961; called by muse, mutect2
- GPR156 | c.2392C>T p.R798C | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs748625030; called by muse, mutect2, varscan2
- GTF3C3 | c.2159G>A p.R720H | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as rs1289249906; called by muse, mutect2
- ITIH6 | c.2581C>A p.P861T | Missense Mutation (SNP) | VAF 56/302 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.185); catalogued as COSV99513647; called by muse, mutect2, varscan2
- KCNQ2 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 80/464 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs756153757, COSV100609380; called by muse, mutect2, varscan2
- KCNQ5 | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 30/105 reads (29%) | catalogued as rs1554213240, COSV100573305; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLK4 | c.289G>T p.V97L | Missense Mutation (SNP) | VAF 157/477 reads (33%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV60677367; called by muse, mutect2, varscan2
- KRTAP26-1 | c.430C>A p.R144S | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as rs371533379; called by muse, mutect2, varscan2
- LINGO2 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 68/264 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as rs750277332; called by muse, mutect2, varscan2
- LPAR5 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 67/266 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs764003076, COSV61693055; called by muse, mutect2, varscan2
- LRRC8E | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 48/423 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376889961; called by muse, mutect2, varscan2
- LTBP1 | c.1782C>G p.C594W (on ENST00000404816 / NM_206943.4; = p.C268W on NM_000627.4) | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100616832; called by muse, mutect2
- MAP9 | c.218T>G p.M73R | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV60903473; called by muse, mutect2, varscan2
- MGAT3 | c.934G>A p.V312I | Missense Mutation (SNP) | VAF 90/302 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.348); catalogued as COSV57866421; called by muse, mutect2, varscan2
- MORF4L2 | c.487G>T p.A163S | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV64611361; called by muse, mutect2, varscan2
- MPP7 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100517237; called by mutect2, varscan2
- MYH2 | c.1360C>A p.Q454K | Missense Mutation (SNP) | VAF 71/313 reads (23%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.614); catalogued as rs895972095; called by muse, mutect2, varscan2
- MYO1G | c.964G>A p.V322M | Missense Mutation (SNP) | VAF 102/485 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.418); catalogued as rs529814356; called by muse, mutect2, varscan2
- NFATC2 | c.2338G>A p.A780T | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs772057890, COSV65356607; called by muse, mutect2, varscan2
- NOS2 | c.1860G>C p.R620S | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.331); catalogued as COSV99047428; called by muse, mutect2, varscan2
- OR2L3 | c.913C>A p.Q305K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV100741945; called by muse, mutect2, varscan2
- PCDH11X | c.3501G>T p.Q1167H | Missense Mutation (SNP) | VAF 62/413 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.205); catalogued as COSV53505483; called by muse, mutect2, varscan2
- PCDHB12 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.963); catalogued as rs376801357, COSV53400949; called by muse, mutect2, varscan2
- PHLDB1 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as rs564595248, COSV61878780; called by muse, mutect2, varscan2
- PIK3C2G | c.1849G>C p.A617P (on ENST00000676171; = p.A576P on NM_004570.5) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56833918; called by muse, mutect2
- PLPPR2 | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.201); catalogued as rs757929946, COSV99264390; called by muse, mutect2, varscan2
- PNCK | c.397G>A p.V133M (on ENST00000340888 / NM_001366975.1; = p.V216M on NM_001039582.3) | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1557040008, COSV61744260; called by muse, mutect2
- POU4F3 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 71/405 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57942451; called by muse, mutect2, varscan2
- PSG7 | c.493G>C p.V165L | Missense Mutation (SNP) | VAF 56/251 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.517); catalogued as COSV101343168; called by muse, mutect2, varscan2
- PTPN21 | c.2417G>A p.R806H | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.852); catalogued as rs1379819676; called by muse, mutect2, varscan2
- PTPRC | c.3527C>T p.T1176M | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773582172, COSV100722019; called by muse, mutect2, varscan2
- PTPRD | c.5146G>A p.A1716T | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs200354236, COSV100647843, COSV61941985; called by muse, mutect2, varscan2
- RASSF4 | c.159C>G p.I53M | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as COSV53573599, COSV53573723; called by muse, mutect2, varscan2
- RGS17 | c.377A>G p.K126R | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs1200081962; called by muse, mutect2, varscan2
- RNF25 | c.1379A>G p.*460Wext*? | Nonstop Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as COSV55307475; called by muse, mutect2, varscan2
- RYR1 | c.7798C>T p.R2600C | Missense Mutation (SNP) | VAF 36/500 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1480598842; ClinVar: uncertain significance; called by muse, mutect2
- SIGLEC6 | c.215C>A p.A72D | Missense Mutation (SNP) | VAF 77/310 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.303); catalogued as COSV58436997; called by muse, mutect2, varscan2
- SKA2 | c.203C>G p.A68G | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV57523496; called by muse, mutect2, varscan2
- SLC10A3 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 27/220 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV54835982; called by muse, mutect2, varscan2
- SLC6A14 | c.1306C>T p.Q436* | Nonsense Mutation (SNP) | VAF 26/88 reads (30%) | catalogued as COSV100903084; called by muse, mutect2, varscan2
- SLC6A15 | c.2149T>G p.L717V | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.082); catalogued as COSV57023288, COSV99881044; called by muse, mutect2, varscan2
- SLITRK5 | c.2186C>T p.A729V | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV61520618; called by muse, varscan2
- SPATS1 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 82/162 reads (51%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.843); catalogued as rs1314812573, COSV55823856; called by muse, mutect2, varscan2
- SPTY2D1 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as rs775529304; called by muse, mutect2, varscan2
- THAP10 | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as rs372754529; called by muse, mutect2, varscan2
- THSD7A | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 82/385 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs552018287, COSV70267169; called by muse, mutect2, varscan2
- TMEM86B | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 38/337 reads (11%) | SIFT tolerated (0.92); PolyPhen benign (0.018); catalogued as rs191683509, COSV100497634; called by muse, mutect2, varscan2
- USH2A | c.11532A>G p.I3844M | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs765306173; called by muse, mutect2, varscan2
- WDR87 | c.4808C>A p.A1603E | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV58205657; called by muse, mutect2, varscan2
- XIRP2 | c.6712A>G p.T2238A (on ENST00000628543; = p.T2413A on NM_152381.6) | Missense Mutation (SNP) | VAF 65/156 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV54693222; called by muse, mutect2, varscan2
- ZNF292 | c.4385C>T p.S1462L | Missense Mutation (SNP) | VAF 121/263 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs757750690, COSV100370607; called by muse, mutect2, varscan2
- ZNRF4 | c.580G>A p.V194M | Missense Mutation (SNP) | VAF 92/627 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as rs772798929; called by muse, mutect2, varscan2
- ABCA13 | c.15147C>A p.D5049E | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ADAMTSL3 | c.3623C>A p.T1208K | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ADGB | c.3653G>T p.R1218I | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.165); called by muse, mutect2
- AGRN | c.2371+1G>A p.X791_splice | Splice Site (SNP) | VAF 135/441 reads (31%) | called by muse, mutect2, varscan2
- AMOT | c.155G>A p.S52N | Missense Mutation (SNP) | VAF 14/295 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2
- AP2A2 | c.670A>C p.T224P | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- APOC1 | c.46A>C p.I16L | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- ARHGAP23 | c.3182G>A p.G1061E | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATR | c.3819+2T>A p.X1273_splice | Splice Site (SNP) | VAF 16/143 reads (11%) | called by muse, mutect2, varscan2
- ATRX | c.1379del p.S460* | Frame Shift Del (DEL) | VAF 38/224 reads (17%) | called by mutect2, pindel, varscan2
- AUTS2 | c.1329C>A p.S443R | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2
- B3GALT5 | c.187G>A p.V63M | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- BRAT1 | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 12/200 reads (6%) | called by muse, mutect2
- C8orf34 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious, low confidence (0.03); called by muse, mutect2, varscan2
- CARMIL3 | c.3733C>T p.Q1245* | Nonsense Mutation (SNP) | VAF 9/157 reads (6%) | called by muse, mutect2
- CCNT2 | c.1054C>G p.P352A | Missense Mutation (SNP) | VAF 106/350 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- CEACAM18 | c.958C>A p.L320I | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CHST7 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 45/403 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- CSMD3 | c.2012T>G p.L671* (on ENST00000297405 / NM_001363185.1; = p.L567* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 9/261 reads (3%) | called by muse, mutect2
- CYP17A1 | c.1115C>A p.P372H | Missense Mutation (SNP) | VAF 44/361 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CYTL1 | c.173T>A p.L58Q | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- DAPK2 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- DNASE1 | c.592G>A p.V198M | Missense Mutation (SNP) | VAF 114/709 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK2 | c.4526T>G p.I1509S | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPYS | c.827G>T p.S276I | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); called by muse, mutect2
- DSP | c.3144C>A p.N1048K | Missense Mutation (SNP) | VAF 12/201 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.351); called by muse, mutect2
- DYNC2H1 | c.9512C>T p.A3171V | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.223); called by muse, mutect2
- FMR1 | c.1472-6C>A | Splice Region (SNP) | VAF 13/142 reads (9%) | called by muse, mutect2
- GNA11 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.795); called by muse, mutect2
- GOLGA6D | c.395T>A p.L132* | Nonsense Mutation (SNP) | VAF 23/550 reads (4%) | called by muse, mutect2
- HEPN1 | c.267A>T p.*89Cext*83 | Nonstop Mutation (SNP) | VAF 15/124 reads (12%) | called by muse, mutect2, varscan2
- HFE | c.946T>A p.F316I | Missense Mutation (SNP) | VAF 44/592 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0.01); called by muse, mutect2
- HK3 | c.535-1G>T p.X179_splice | Splice Site (SNP) | VAF 43/193 reads (22%) | called by muse, mutect2, varscan2
- HOOK2 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HYDIN | c.12754C>A p.Q4252K | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- IFRD2 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 56/236 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- IGKV1D-17 | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 94/970 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.361); called by muse, mutect2
- IQGAP2 | c.1299G>A p.W433* | Nonsense Mutation (SNP) | VAF 24/94 reads (26%) | called by muse, mutect2, varscan2
- KDR | c.120A>G p.I40M | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KIAA1549 | c.1528G>T p.E510* | Nonsense Mutation (SNP) | VAF 88/264 reads (33%) | called by muse, mutect2, varscan2
- KIFAP3 | c.718_720del p.E240del | In Frame Del (DEL) | VAF 5/54 reads (9%) | called by pindel, varscan2
- KMT2D | c.14263dup p.T4755Nfs*27 | Frame Shift Ins (INS) | VAF 33/140 reads (24%) | called by mutect2, pindel, varscan2
- LEPR | c.2542G>C p.V848L | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LRRC36 | c.821A>G p.Y274C | Missense Mutation (SNP) | VAF 36/230 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- MAGEA3 | c.-64C>G | Splice Region (SNP) | VAF 140/692 reads (20%) | called by muse, mutect2, varscan2
- MGA | c.3385G>T p.E1129* | Nonsense Mutation (SNP) | VAF 16/97 reads (16%) | called by muse, mutect2, varscan2
- MMP26 | c.114A>T p.Q38H | Missense Mutation (SNP) | VAF 26/253 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MROH1 | c.3634G>T p.A1212S | Missense Mutation (SNP) | VAF 89/410 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NF1 | c.4026G>T p.M1342I | Missense Mutation (SNP) | VAF 28/248 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLRP14 | c.2699A>G p.K900R | Missense Mutation (SNP) | VAF 87/355 reads (25%) | SIFT tolerated (0.92); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- NUP160 | c.2683A>G p.I895V | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR11L1 | c.192G>T p.Q64H | Missense Mutation (SNP) | VAF 61/243 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- OR4K13 | c.384A>C p.K128N | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- OR4Q3 | c.729C>A p.N243K | Missense Mutation (SNP) | VAF 28/441 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.037); called by muse, mutect2
- OR52A1 | c.637G>T p.D213Y | Missense Mutation (SNP) | VAF 49/323 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OVCA2 | c.486C>G p.I162M | Missense Mutation (SNP) | VAF 77/209 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- PCDH11X | c.2458G>T p.G820C | Missense Mutation (SNP) | VAF 16/433 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHGA8 | c.2093C>A p.A698D | Missense Mutation (SNP) | VAF 84/321 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PIK3CA | c.1254_1261delinsCA p.E418_P421delinsDT | Splice Region (DEL) | VAF 10/24 reads (42%) | called by pindel, varscan2*
- PKLR | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 92/455 reads (20%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- PNN | c.1162G>T p.D388Y | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PPFIA2 | c.58T>G p.S20A | Missense Mutation (SNP) | VAF 12/239 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.107); called by muse, mutect2
- PRKCZ | c.342C>G p.I114M | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- RAB8A | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RELN | c.9119A>C p.Q3040P | Missense Mutation (SNP) | VAF 40/406 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.394); called by muse, mutect2
- RIPK4 | c.926T>C p.L309P | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RIPOR1 | c.3530C>A p.T1177K (on ENST00000379312 / NM_001193522.2; = p.T1173K on NM_024519.4) | Missense Mutation (SNP) | VAF 63/307 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- RPGRIP1 | c.3514del p.H1172Tfs*7 | Frame Shift Del (DEL) | VAF 14/91 reads (15%) | called by mutect2, pindel, varscan2
- RRAGB | c.120G>T p.K40N | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- SAMSN1 | c.629A>G p.K210R | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCUBE2 | c.2201C>T p.A734V (on ENST00000649792 / NM_001367977.2; = p.A677V on NM_020974.3) | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SEMA6B | c.899T>A p.F300Y | Missense Mutation (SNP) | VAF 34/243 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- SMARCA2 | c.3959T>G p.L1320R | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SMPDL3A | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, mutect2
- SNTG1 | c.677G>T p.S226I | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SPARC | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- SPG11 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 11/258 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.099); called by muse, mutect2
- SPTBN4 | c.519_520del p.E174Gfs*25 | Frame Shift Del (DEL) | VAF 44/114 reads (39%) | called by mutect2, varscan2
- TET3 | c.3305G>A p.G1102D | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- TNC | c.940A>C p.I314L | Missense Mutation (SNP) | VAF 113/580 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRHDE | c.1704G>C p.W568C | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRIB2 | c.959_970del p.G320_E323del | In Frame Del (DEL) | VAF 68/269 reads (25%) | called by mutect2, varscan2
- ZIC3 | c.818G>T p.S273I | Missense Mutation (SNP) | VAF 138/635 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ZNF267 | c.722A>G p.E241G | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); called by muse, mutect2
- ZNF334 | c.335G>T p.R112I | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.352); called by muse, mutect2
- ZNF679 | c.781A>G p.I261V | Missense Mutation (SNP) | VAF 70/223 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF679 | c.1078G>T p.A360S | Missense Mutation (SNP) | VAF 62/286 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- ZNF808 | c.659A>G p.Q220R | Missense Mutation (SNP) | VAF 19/321 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.186); called by muse, mutect2
- ZNF98 | c.1618C>A p.H540N | Missense Mutation (SNP) | VAF 81/240 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AKAP14 | c.249C>T p.D83= | Silent (SNP) | VAF 29/298 reads (10%) | catalogued as rs753496334, COSV57629816; called by muse, mutect2
- AURKA | c.415C>T p.L139= | Silent (SNP) | VAF 45/386 reads (12%) | catalogued as rs1363988473, COSV57169496; called by muse, mutect2, varscan2
- CACHD1 | c.2988C>T p.C996= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs150699745; called by muse, mutect2, varscan2
- CACNA1E | c.21G>A p.A7= | Silent (SNP) | VAF 45/105 reads (43%) | called by muse, mutect2, varscan2
- CACNA1I | c.3069C>T p.D1023= | Silent (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2
- CACNA2D4 | c.417G>A p.E139= | Silent (SNP) | VAF 18/191 reads (9%) | called by muse, mutect2
- CDC14C | c.1257G>A p.A419= (on ENST00000428251; = p.A312= on NM_152627.3) | Silent (SNP) | VAF 111/761 reads (15%) | catalogued as rs780024500; called by muse, mutect2, varscan2
- CDH13 | c.1506G>A p.T502= | Silent (SNP) | VAF 55/134 reads (41%) | catalogued as rs184869802, COSV51868182; called by muse, mutect2, varscan2
- CDK19 | c.84A>G p.G28= | Silent (SNP) | VAF 44/94 reads (47%) | called by muse, mutect2, varscan2
- CHST3 | c.927G>A p.S309= | Silent (SNP) | VAF 98/350 reads (28%) | catalogued as rs1013851768, COSV64151228; called by muse, mutect2, varscan2
- COL12A1 | c.8154C>T p.D2718= | Silent (SNP) | VAF 23/148 reads (16%) | called by muse, mutect2, varscan2
- COL9A2 | c.918C>T p.N306= | Silent (SNP) | VAF 57/292 reads (20%) | catalogued as rs376991606; called by muse, mutect2, varscan2
- CRYGA | c.99C>T p.C33= | Silent (SNP) | VAF 12/291 reads (4%) | called by muse, mutect2
- CYP11B1 | c.867C>T p.I289= | Silent (SNP) | VAF 24/593 reads (4%) | catalogued as rs1186627183; called by muse, mutect2
- DNAH17 | c.4431G>A p.Q1477= | Silent (SNP) | VAF 17/378 reads (4%) | catalogued as rs1430558117; called by muse, mutect2
- DNMT3B | c.1446C>T p.C482= | Silent (SNP) | VAF 74/361 reads (20%) | catalogued as rs898296778, COSV52419162; called by muse, mutect2, varscan2
- FAT2 | c.5538A>C p.G1846= | Silent (SNP) | VAF 19/226 reads (8%) | catalogued as COSV99942055; called by muse, mutect2
- FGD3 | c.276C>T p.C92= | Silent (SNP) | VAF 86/306 reads (28%) | catalogued as rs374597995; called by muse, mutect2, varscan2
- FGF9 | c.529A>C p.R177= | Silent (SNP) | VAF 86/548 reads (16%) | called by muse, mutect2, varscan2
- FOXA3 | c.747C>T p.S249= | Silent (SNP) | VAF 11/280 reads (4%) | called by muse, mutect2
- HSPA6 | c.870C>T p.F290= | Silent (SNP) | VAF 194/647 reads (30%) | catalogued as rs759271260, COSV59060583; called by muse, mutect2, varscan2
- HUWE1 | c.1260C>T p.G420= | Silent (SNP) | VAF 32/242 reads (13%) | catalogued as rs782704612; called by muse, varscan2
- IGKV1D-13 | c.129C>A p.I43= | Silent (SNP) | VAF 162/758 reads (21%) | called by muse, mutect2, varscan2
- INHBA | c.483C>T p.V161= | Silent (SNP) | VAF 22/184 reads (12%) | catalogued as COSV54225857; called by muse, mutect2, varscan2
- IRX5 | c.930T>C p.G310= | Silent (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- KCNA5 | c.801C>T p.F267= | Silent (SNP) | VAF 20/536 reads (4%) | called by muse, mutect2
- KMT2A | c.9297C>T p.T3099= | Silent (SNP) | VAF 26/306 reads (8%) | called by muse, mutect2
- MARS1 | c.123G>A p.P41= | Silent (SNP) | VAF 30/109 reads (28%) | called by muse, mutect2, varscan2
- MGMT | c.516C>T p.I172= (on ENST00000306010; = p.I141= on NM_002412.5) | Silent (SNP) | VAF 17/121 reads (14%) | called by muse, mutect2, varscan2
- MICU1 | c.1413C>T p.F471= (on ENST00000361114 / NM_001195518.2; = p.F477= on NM_006077.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/128 reads (31%) | catalogued as rs539250393, COSV63144014; called by muse, mutect2, varscan2
- MRPL36 | c.90A>G p.L30= | Silent (SNP) | VAF 57/215 reads (27%) | catalogued as rs749561344, COSV56876308; called by muse, mutect2, varscan2
- MYLK | c.225C>T p.S75= | Silent (SNP) | VAF 46/438 reads (11%) | catalogued as rs371699704, COSV100658878; ClinVar: likely benign; called by muse, mutect2, varscan2
- NMRK2 | c.51G>A p.T17= | Silent (SNP) | VAF 48/119 reads (40%) | catalogued as rs1408280814; called by muse, mutect2, varscan2
- NR0B1 | c.489C>T p.P163= | Silent (SNP) | VAF 126/668 reads (19%) | catalogued as rs1479049803; called by muse, mutect2, varscan2
- OFD1 | c.1539C>T p.D513= | Silent (SNP) | VAF 50/290 reads (17%) | catalogued as rs1480093399, COSV60799118; called by muse, varscan2
- PCDH17 | c.2232C>T p.I744= | Silent (SNP) | VAF 64/354 reads (18%) | catalogued as rs769907429, COSV100932226, COSV64978049; called by muse, mutect2, varscan2
- PCDH8 | c.2154G>A p.P718= | Silent (SNP) | VAF 40/165 reads (24%) | called by muse, mutect2, varscan2
- PCDHGA12 | c.2139G>A p.A713= | Silent (SNP) | VAF 142/581 reads (24%) | catalogued as rs746913952; called by muse, mutect2, varscan2
- PDE6A | c.1404C>A p.I468= | Silent (SNP) | VAF 32/410 reads (8%) | catalogued as rs751748166; called by muse, mutect2
- PER3 | c.543G>A p.A181= | Silent (SNP) | VAF 28/163 reads (17%) | catalogued as rs750025676, COSV100728457, COSV62704271; called by muse, mutect2, varscan2
- PRDM1 | c.1473G>A p.A491= | Silent (SNP) | VAF 147/259 reads (57%) | catalogued as rs747183412, COSV64846091; called by muse, mutect2, varscan2
- SGSM1 | c.1059C>T p.F353= | Silent (SNP) | VAF 32/160 reads (20%) | catalogued as COSV68513446; called by muse, mutect2, varscan2
- SH3RF3 | c.1329C>T p.P443= | Silent (SNP) | VAF 54/167 reads (32%) | called by muse, mutect2, varscan2
- SPHKAP | c.3327G>A p.P1109= | Silent (SNP) | VAF 33/251 reads (13%) | catalogued as rs199683355; called by muse, mutect2, varscan2
- STAB2 | c.6309C>A p.G2103= | Silent (SNP) | VAF 43/197 reads (22%) | called by muse, mutect2, varscan2
- SUSD6 | c.630C>T p.S210= | Silent (SNP) | VAF 16/199 reads (8%) | catalogued as rs770132194; called by muse, mutect2
- TBC1D3F | c.1134C>T p.G378= | Silent (SNP) | VAF 22/228 reads (10%) | catalogued as rs1423024898; called by muse, mutect2
- THRB | c.1059C>A p.I353= | Silent (SNP) | VAF 21/266 reads (8%) | catalogued as COSV54979538; called by muse, mutect2
- TLX3 | c.117C>T p.D39= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as rs1409056428; called by muse, mutect2, varscan2
- TMEM151B | c.660G>A p.T220= | Silent (SNP) | VAF 138/240 reads (58%) | catalogued as rs1456026555; called by muse, mutect2, varscan2
- TTC6 | c.529C>A p.R177= | Silent (SNP) | VAF 12/143 reads (8%) | called by muse, mutect2
- UNC79 | c.2526C>T p.P842= (on ENST00000393151 / NM_001346218.2; = p.P665= on NM_020818.5) | Silent (SNP) | VAF 36/183 reads (20%) | called by muse, mutect2, varscan2
- VPS18 | c.2112C>T p.C704= | Silent (SNP) | VAF 117/399 reads (29%) | catalogued as rs779440413; called by muse, mutect2, varscan2
- WASHC2A | c.3333G>A p.V1111= | Silent (SNP) | VAF 105/586 reads (18%) | called by muse, mutect2, varscan2
- XPOT | c.1827G>A p.P609= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as rs754880442; called by muse, mutect2, varscan2
- ZNF550 | c.363G>A p.S121= | Silent (SNP) | VAF 56/310 reads (18%) | catalogued as rs138647268; called by muse, mutect2, varscan2
- ADAM33 | c.1133+34C>A | Intron (SNP) | VAF 58/343 reads (17%) | catalogued as rs746484033; called by muse, mutect2, varscan2
- AP3S1 | chr5:115841678 G>A | 5'Flank (SNP) | VAF 28/118 reads (24%) | called by muse, mutect2, varscan2
- ARHGEF1 | c.2655+12C>T | Intron (SNP) | VAF 10/111 reads (9%) | catalogued as rs552569257; called by muse, mutect2
- C1orf159 | c.*51G>A | 3'UTR (SNP) | VAF 50/136 reads (37%) | catalogued as rs1248961459; called by muse, mutect2, varscan2
- CD84 | c.812-44dup | Intron (INS) | VAF 19/76 reads (25%) | catalogued as rs572194057; called by mutect2, varscan2
- CEP41 | c.*1874G>C | 3'UTR (SNP) | VAF 9/221 reads (4%) | called by muse, mutect2
- CLCN6 | c.*6C>A | 3'UTR (SNP) | VAF 50/169 reads (30%) | called by muse, mutect2, varscan2
- COG6 | c.*832A>G | 3'UTR (SNP) | VAF 77/346 reads (22%) | called by muse, mutect2, varscan2
- COX7A1 | c.-16A>C | 5'UTR (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- CXCR2P1 | n.789A>G | RNA (SNP) | VAF 26/526 reads (5%) | called by muse, mutect2
- DLG1 | c.2004+11G>T | Intron (SNP) | VAF 9/81 reads (11%) | called by muse, mutect2, varscan2
- FAM157B | n.452C>T | RNA (SNP) | VAF 10/107 reads (9%) | catalogued as rs1240849463; called by muse, mutect2, varscan2
- FAM160B1 | c.-58G>A | 5'UTR (SNP) | VAF 10/24 reads (42%) | catalogued as rs1365633535; called by muse, mutect2, varscan2
- FAM183BP | n.1005T>A | RNA (SNP) | VAF 45/552 reads (8%) | called by muse, mutect2
- FRMPD4 | c.-69G>A | 5'UTR (SNP) | VAF 5/102 reads (5%) | catalogued as rs1421235077, COSV66211965; called by muse, mutect2
- HLA-C | c.*1G>C | 3'UTR (SNP) | VAF 6/111 reads (5%) | catalogued as rs774174568; called by muse, mutect2
- KDR | c.2615-46G>C | Intron (SNP) | VAF 24/110 reads (22%) | called by muse, mutect2, varscan2
- MIR7-2 | n.15G>T | RNA (SNP) | VAF 18/95 reads (19%) | called by muse, mutect2, varscan2
- MYBPC1 | c.104-16C>T | Intron (SNP) | VAF 78/308 reads (25%) | called by muse, mutect2, varscan2
- PARVB | c.113-24812G>A | Intron (SNP) | VAF 18/94 reads (19%) | catalogued as rs771779713; called by muse, mutect2, varscan2
- PCK2 | c.29+716C>T | Intron (SNP) | VAF 50/193 reads (26%) | called by muse, mutect2, varscan2
- PFKFB3 | c.-43G>A | 5'UTR (SNP) | VAF 33/133 reads (25%) | catalogued as rs762968358; called by muse, mutect2, varscan2
- RHD | c.1073+1006G>C | Intron (SNP) | VAF 9/122 reads (7%) | called by muse, mutect2
- RUFY2 | c.1705-11C>T | Intron (SNP) | VAF 5/52 reads (10%) | catalogued as rs1382258180; called by muse, mutect2, varscan2
- SHROOM4 | c.*1074A>T | 3'UTR (SNP) | VAF 18/473 reads (4%) | called by muse, mutect2
- SMG1P6 | n.2221C>T | RNA (SNP) | VAF 109/249 reads (44%) | catalogued as rs1162067582; called by muse, mutect2, varscan2
- SNORD116-17 | chr15:25087953 C>A | 3'Flank (SNP) | VAF 77/352 reads (22%) | called by muse, mutect2, varscan2
- SSPOP | n.5460G>T | RNA (SNP) | VAF 57/194 reads (29%) | called by muse, mutect2, varscan2
- TRIM61 | c.526-2348C>G | Intron (SNP) | VAF 37/202 reads (18%) | catalogued as rs762241013, COSV61417641; called by muse, mutect2, varscan2
- TUBB8 | c.167-26C>T | Intron (SNP) | VAF 69/340 reads (20%) | catalogued as rs551052619; called by muse, mutect2, varscan2
- ZNF99 | c.*682G>T | 3'UTR (SNP) | VAF 72/253 reads (28%) | catalogued as COSV68055893; called by muse, mutect2, varscan2
